Surgical pathology report (de-identified scan), TCGA case TCGA-XY-A89B, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Spectrum Health, specimen TCGA-XY-A89B-01A (Primary Tumor).

[page 1 of 2]
Research Gross Description

Research Dx

Right testicle, orchiectomy

Seminoma.

See case summary.

CASE SUMMARY FOR TESTIS (RADICAL ORCHIECTOMY):

Tumor focality: Multifocal

Tumor size:

Greatest dimension: 2.6 cm

Additional measurements: 2.5 x 2 cm

Macroscopic extent of tumor: Tumor confined to testis

Histologic type: Classic seminoma

Margins:

Spermatic cord margin: Negative for seminoma

Other margins: Negative for seminoma

Microscopic tumor extension: Tumor confined to testis

Lymphovascular invasion: Not identified

Pathologic staging (pTNM):

Primary tumor: pT1, tumor limited to testis and epididymus without vascular/lymphatic invasion

Regional lymph nodes: pNx, unknown

Number examined: Not applicable

Number involved: Not applicable

Distant metastasis: Not applicable

Serum tumor markers:

LD: 201 U/L

beta-HCG: <1 mIU/mL

AFP: 3.7 ng/mL

Additional pathologic findings: Intratubular germ cell neoplasia; microlithiasis

AJCC Staging (7th edition) pT1 pNx pM: Not applicable

Research QC

Tumor:

75% tumor nuclei

0% necrosis

25% normal

Normal:

95% testis with focal ITGCN (5%)

Research Specimen

-

Specimen Process Time

Plasma/serum/buffy coat

Cold ischemia start time:

Plasma frozen @

Serum frozen @

Buffy coat frozen @

ICD-O-3

Seminoma NOS 9061/3

Sub @ Testis NOS C62.9

4/11/22/13

[page 2 of 2]
Tissue:

Cold ischemia start time:

Formalin fixation start time:

Total cold ischemia time:

Formalin fixation stop time:

Total formalin fixation time:

Specimen Weight

Normal

1- 115 mg, 2- 90 mg

Tumor

1- 89 mg, 2- 116 mg

Specimen Size

Plasma x 3

Serum x 2

Buffy coat x 1

Cryovials x 4

Normal x 2

Tumor x 2

Metastatic - N/A

FFPE x 4

Normal x 2

Tumor x 2

Metastatic - N/A

Study

Patient Consent

Yes

Criteria:	aw 10/24/13	Yes	No
NIH/AA Discrepancy			✓
Reviewer (Initials)	2	Date Reviewed	10/24/13

Source: NCI Genomic Data Commons file af3b648a-bb23-4ac3-aec4-7a0ed4ea436f (TCGA-XY-A89B.109D987A-BE31-4A0D-9510-0AFF38A546D9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).